Somatic mutation profile of tumor specimen MMRF_1219_2_BM_CD138pos (aliquot MMRF_1219_2_BM_CD138pos_T2_KBS5U_L05856) from MMRF case MMRF_1219, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.1 years (25,601 days).
Specimen MMRF_1219_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 543dd9b8-4fed-4913-9af1-2dd15b907c4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1219_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1219_2_PB_Whole_C1_KBS5U_L05765; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/000f237f-f77b-46db-ac6b-00b127be25cf

The open-access MAF lists 77 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 24, Missense Mutation 21, Silent 10, Intron 9, In Frame Del 3, Frame Shift Del 3, 5'UTR 2, 5'Flank 2, Splice Region 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 15/46 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CLDN4 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs781811608, COSV99035141; called by muse, mutect2
- DKK2 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.071); catalogued as rs374083904; called by muse, mutect2, varscan2
- EPB41L1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52438587; called by muse, mutect2, varscan2
- IGHV2-70 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs371469802; called by muse, varscan2
- IGHV2-70D | c.158T>C p.M53T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs1555598153; called by muse, varscan2
- IGKV1-5 | c.57T>A p.G19= | Splice Region (SNP) | VAF 9/33 reads (27%) | catalogued as rs530103870; called by muse, varscan2
- IGLV2-14 | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as rs371955257; called by muse, varscan2
- IGLV2-14 | c.356A>G p.H119R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as rs1568992464; called by muse, varscan2
- PC | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58920961; called by muse, mutect2, varscan2
- RAC3 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs760585885, COSV60711965; called by muse, mutect2, varscan2
- TRIM3 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.86); catalogued as rs1274455544, COSV100624271; called by muse, mutect2, varscan2
- AMER1 | c.3145_3146del p.D1050Cfs*6 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- COL4A6 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); called by muse, mutect2
- F2R | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- GPR75 | c.45_83del p.H17_L29del | In Frame Del (DEL) | VAF 5/40 reads (13%) | called by mutect2*, pindel
- IGHV2-70D | c.242del p.S81Tfs*4 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | called by pindel, varscan2
- IGKV1-5 | c.292A>C p.S98R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.168); called by muse, mutect2
- IGKV1D-43 | c.158G>C p.S53T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT9 | c.1809_1847del p.E604_G616del | In Frame Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- LDOC1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLVAP | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPL | c.3375_3422del p.T1126_A1141del | In Frame Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- SENP1 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.048); called by muse, mutect2
- SNTB1 | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); called by mutect2, varscan2
- SPO11 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1248del p.G418Vfs*105 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel
- UBA52 | c.58A>G p.S20G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF99 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ARRDC4 | c.66G>A p.L22= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- COX5B | c.75G>A p.A25= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- HRNR | c.636C>T p.S212= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs201296154, COSV64257258; called by muse, mutect2, varscan2
- IGKV1D-8 | c.93C>T p.S31= | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as rs1453423481; called by muse, mutect2, varscan2
- IMPDH1 | c.957G>A p.G319= (on ENST00000470772 / NM_001142573.2; = p.G405= on NM_000883.4) | Silent (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- NES | c.3138A>G p.Q1046= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- POLR3B | c.2889G>T p.A963= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV57285198; called by muse, mutect2, varscan2
- PRICKLE1 | c.708C>T p.R236= | Silent (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- SLC7A6OS | c.162C>T p.V54= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- TRPS1 | c.2691C>G p.A897= (on ENST00000220888 / NM_001330599.2; = p.A910= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- ACTR1A | c.*78A>G | 3'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- ALDOB | c.*690T>C | 3'UTR (SNP) | VAF 41/70 reads (59%) | called by muse, varscan2
- ALDOB | c.*591C>G | 3'UTR (SNP) | VAF 42/69 reads (61%) | called by muse, varscan2
- ALDOB | c.*505C>G | 3'UTR (SNP) | VAF 32/54 reads (59%) | called by muse, varscan2
- BTK | c.*5G>A | 3'UTR (SNP) | VAF 5/30 reads (17%) | catalogued as rs1569289843, COSV100437954; called by muse, mutect2, varscan2
- BTNL8 | c.49+3001C>A | Intron (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- CALD1 | c.*167C>T | 3'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as rs1416988950; called by muse, mutect2, varscan2
- CD63 | c.256-24G>C | Intron (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2
- COLCA2 | chr11:111297735 T>A | 5'Flank (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- DHX36 | c.*1785T>A | 3'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- DNM1P46 | chr15:99807932 G>A | 5'Flank (SNP) | VAF 4/31 reads (13%) | called by muse, varscan2
- EDN1 | c.-11T>C | 5'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- EFHC2 | c.*815del | 3'UTR (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- ENPP2 | c.-32C>T | 5'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- FIS1 | c.45+56G>A | Intron (SNP) | VAF 7/20 reads (35%) | catalogued as rs377576120; called by muse, mutect2, varscan2
- KIAA0319L | c.*1028G>A | 3'UTR (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- LIF | c.*2088C>T | 3'UTR (SNP) | VAF 9/20 reads (45%) | catalogued as rs1464172570, COSV50777139; called by muse, mutect2, varscan2
- LINC00940 | n.1426_1449del | RNA (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel*
- LRATD2 | c.*3897A>G | 3'UTR (SNP) | VAF 8/32 reads (25%) | called by muse, varscan2
- MCPH1 | c.1825+914G>A | Intron (SNP) | VAF 5/49 reads (10%) | catalogued as rs1429980618; called by muse, mutect2
- MOB3B | c.*4623del | 3'UTR (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel
- PGGT1B | c.*683del | 3'UTR (DEL) | VAF 14/103 reads (14%) | catalogued as COSV101101946; called by mutect2, pindel
- POLE | c.5553-45del | Intron (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- PSD3 | c.2175+2454C>A | Intron (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- RALGPS1 | c.*836C>T | 3'UTR (SNP) | VAF 37/60 reads (62%) | called by muse, mutect2, varscan2
- RASAL2 | c.*1031T>C | 3'UTR (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- SAPCD2 | c.*1993C>T | 3'UTR (SNP) | VAF 11/21 reads (52%) | catalogued as rs1051681479; called by muse, mutect2, varscan2
- SETBP1 | c.*3859A>G | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- SETD6 | c.28-16C>T | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs547670330; called by mutect2, varscan2
- SLC17A5 | c.*3G>A | 3'UTR (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- SMG5 | c.*143dup | 3'UTR (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- SRRM2 | c.350+11C>T | Intron (SNP) | VAF 9/23 reads (39%) | catalogued as rs536410598; called by muse, mutect2, varscan2
- STAMBP | c.*834T>C | 3'UTR (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- TACC1 | c.*3619T>A | 3'UTR (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.*4757G>T | 3'UTR (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- VGLL4 | c.65-41584_65-41583del | Intron (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel
- VPS26B | c.*1373T>G | 3'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- ZNF148 | c.*1272A>T | 3'UTR (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
